Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A925, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A925-01A (Primary Tumor).

[illegible]

ICD-O-3
Adenocarcinoma, tubular 8211.3
Site: Gastric antrum C16.3
JWB 8/14

PRIMARY SITE: Stomach (Antrum)

- Adenocarcinoma of intestinal type, tubular, moderately differentiated, ulcerated.
- Lesion size: 7.5 cm
- Level of infiltration: serosa and adjacent adipose tissue.
- Lymphatic and perineural invasions: present.
- Lymph nodes from the lesser curvature affected by metastasis, with extracapsular extension (4/4).
- Presence of multiple neoplastic nodules in the lesser curvature, without lymphoid remnant tissue (see note).
- Distal surgical margin of resection affected by the neoplasia.

- Lymph nodes affected by metastasis, with extracapsular extension (2/2).
- Presence of two neoplastic nodules, without lymphoid tissue remnant (see note).

- Implant of adenocarcinoma.

- Uninvolved by neoplasia.

We can not determine whether the neoplastic nodules are lymph nodes totally replaced by metastasis or implants in adipose tissue.

Topography	Morphology	Stage
Stomach, NOS	Tubular adenocarcinoma	pT4a

[illegible]

Source: NCI Genomic Data Commons file 9b5ab229-88d7-41b2-8256-2da556b76b6b (TCGA-VQ-A925.79B6CF21-C486-4424-8386-786817DDD892.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).